Surgical pathology report (de-identified scan), TCGA case TCGA-3B-A9HZ, project TCGA-SARC (Sarcoma), tissue source site Moffitt Cancer Center, specimen TCGA-3B-A9HZ-01A (Primary Tumor).

[page 1 of 3]
Pathology Report

Final Diagnosis

- A. RIB, RIGHT, RESECTION:
Fragment of rib, gross diagnosis only.
- B. PLEURA, BIOPSY:
Fibroadipose tissue with muscle, negative for malignancy.
- C. SOFT TISSUE, MEDIASTINUM, RESECTION:
Leiomyosarcoma, grade 2 of 3
Sarcoma focally present on a black inked margin.
See Synoptic Report.

I, _____, the attending pathologist, personally reviewed all slides and / or materials and rendered the final diagnosis. Electronically signed out by _____

Comment

Block C10 shows a focus of sarcoma with significant nuclear pleomorphism and associated necrosis. The mitotic count in this area remains at 8/10 HPF.

Key Pathological Findings

C: Soft Tissue Resection

PROCEDURE:

Wide resection

TUMOR SITE:

Mediastinum

TUMOR SIZE:

Greatest dimension: 9.5 cm

MACROSCOPIC EXTENT OF TUMOR:

Mediastinal

HISTOLOGIC TYPE:

Leiomyosarcoma

MITOTIC RATE:

Specify: 8 / 10 high-power fields (HPF)

NECROSIS (MACROSCOPIC OR MICROSCOPIC):

Present

Extent: 20 %

HISTOLOGIC GRADE:

Grade 2

MARGINS:

Margins involved by sarcoma

Specified margin(s): soft tissue

LYMPH-VASCULAR INVASION:

Not identified

PRIMARY TUMOR (pT):

pT2b: Tumor more than 5 cm in greatest dimension, deep tumor

REGIONAL LYMPH NODES (pN):

ICD-O.3
Leiomyosarcoma NOS 8890/3
Site: ^{chest} Chest NOS C49.3
^{path} Mediastinum NOS C38.0
QAD 4/22/14

[page 2 of 3]
pNX: Regional lymph nodes cannot be assessed

DISTANT METASTASIS (pM):

Not applicable

ANCILLARY STUDIES:

Not performed

Not performed

Not performed

PRESECTION TREATMENT:

No therapy

TREATMENT EFFECT:

Cannot be determined

Specimen(s) Received

A RIGHT RIB GROSS ONLY

B PLEURAL BIOPSY FS

C MEDIASTINAL MASS

Clinical History

MEDIASTINAL MASS

Preoperative Diagnosis

Mediastinal mass.

Intraoperative Consultation

FSB1: PLEURAL BIOPSY:

Negative.

Comment: This frozen section diagnosis/result was communicated to and acknowledged by Dr.
OR

I, _____, MD, have performed the intraoperative consultation and issued the above diagnosis.

Gross Description

A. The specimen is labeled "right rib, gross only." The specimen consists of an oriented fragment of rib, which measures up to 1.2 cm in length. Both resection margins are grossly unremarkable. The specimen is received for gross analysis only.

B. The specimen is labeled "pleural biopsy." The specimen consists of an irregular, unoriented fragment of pink-tan, focally hemorrhagic, rubbery tissue measuring 0.7 cm in greatest dimension which is submitted entirely for frozen section as FSB1.

C. The specimen is labeled "mediastinal mass." The specimen consists of an irregular to roughly ovoid, unoriented, rubbery solid tumor mass which measures 9.5 x 7.5 x 6.0 cm. The tumor is partially covered by pink-tan to dusky red, focally erythematous serosa. The remainder of the surface of the tumor is shaggy, focally cauterized and consistent with resection margin. Prior to sectioning, the

[page 3 of 3]
specimen is inked as follows:

Resection margin

Black

Remainder surface of tumor covered by serosa	Blue
--	------

On sectioning, the tumor reveals pink-tan, lobulated cut surface with centrally located area of necrosis and cystic degeneration. The area of necrosis measures up to 3 x 2 x 1.5 cm and occupies less than 10% of the tumor. The tumor extends to within 0.1 cm of the closest resection margin. The tumor bulges but does not appear to extend through the serosa. Representative sections of the specimen are submitted to Tissue Procurement Laboratory. Representative sections of the specimen are submitted in 10 cassettes as follows:

C1-C7: Tumor in relation to closest resection margin

C8-C9: Additional sections of tumor bulging serosa

C10: Central area of tumor

HIPAA Malignancy Site		

Source: NCI Genomic Data Commons file 98a72806-ff94-4ece-b5ea-c4f0550fd87a (TCGA-3B-A9HZ.5EDBED3E-49CC-4EEC-A541-222024FBDCAD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).